Surgical pathology report (de-identified scan), TCGA case TCGA-YU-A94B, project TCGA-TGCT (Testicular Germ Cell Tumors), specimen TCGA-YU-A94B-01A (Primary Tumor).

Collect date:
(MM/DD/YYYY)

ICD O-3
Mixed germ cell tumor 9885/3
Site @ Testis NOS C62.9
JG 3/3/14

PATHOLOGY REPORT:

PRIMARY SITE: Left testis

“Left testis + spermatic cord”:

Mixed germ cell tumor, with the following components:

- Immature teratoma (about 45%).
- Embryonal carcinoma (about 45%).
- Endodermal sinus tumor (about 10%).

Neoplasia with extensive necrotic areas, occupying the entire organ.

Angiolymphatic invasion not detected.

Tunica albuginea and tunica vaginalis uninvolved by neoplasia.

Epididymis, rete testis and spermatic cord uninvolved by neoplasia.

Source: NCI Genomic Data Commons file 2ce2710d-a9f5-417a-968f-68f7a4eff83f (TCGA-YU-A94B-01A.pdf), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).